Somatic mutation profile of tumor specimen TARGET-30-PAKGKH-01A (aliquot TARGET-30-PAKGKH-01A-01W) from TARGET case TARGET-30-PAKGKH, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (882 days).
Specimen TARGET-30-PAKGKH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 162464a2-7de1-4c10-af89-f17ecf1722be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKGKH-10A (Blood Derived Normal), aliquot TARGET-30-PAKGKH-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/940b3f38-553b-4b74-81c2-9211f3169201

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.2796G>A p.W932* | Nonsense Mutation (SNP) | VAF 122/391 reads (31%) | catalogued as COSV52705619; called by muse, mutect2, varscan2
- CYP4F22 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54111966, COSV99512895; called by muse, mutect2
- IPO13 | c.2079C>A p.S693R | Missense Mutation (SNP) | VAF 145/379 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV64894090; called by muse, mutect2, varscan2
- LIX1L | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 16/362 reads (4%) | catalogued as rs140885563; called by muse, mutect2
- MYO18A | c.6082G>A p.D2028N | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs374185220; called by muse, mutect2, varscan2
- RAD51AP2 | c.3194G>C p.S1065T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV67587775; called by muse, mutect2, varscan2
- RCC1 | c.939A>T p.G313= | Splice Region (SNP) | VAF 37/88 reads (42%) | catalogued as COSV65779237; called by muse, mutect2, varscan2
- SATB2 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 28/611 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.197); catalogued as COSV53484122; called by muse, mutect2
- SIX1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 124/267 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs200835641, COSV55959620; called by muse, mutect2, varscan2
- SNX8 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56126145; called by muse, mutect2, varscan2
- TBC1D22B | c.1165+1G>T p.X389_splice | Splice Site (SNP) | VAF 88/162 reads (54%) | catalogued as COSV65142603; called by muse, mutect2, varscan2
- TPST2 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV58679151; called by muse, mutect2, varscan2
- CNN3 | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- DIRAS2 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- KLF7 | c.870del p.R290Sfs*9 | Frame Shift Del (DEL) | VAF 177/548 reads (32%) | called by mutect2, pindel, varscan2
- PSMC4 | c.1035C>G p.F345L | Missense Mutation (SNP) | VAF 24/828 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2
- LCNL1 | c.252G>A p.L84= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56400158; called by muse, mutect2, varscan2
- PDZRN3 | c.1680C>T p.I560= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs1406693110, COSV55195924; called by muse, varscan2
